Somatic mutation profile of tumor specimen TCGA-DY-A1H8-01A (aliquot TCGA-DY-A1H8-01A-21D-A152-10) from TCGA case TCGA-DY-A1H8, project TCGA-READ (Rectum Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Rectum, NOS; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 77.9 years (28,459 days).
Specimen TCGA-DY-A1H8-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 38f10917-b8a3-4fcb-8b6b-df7f28efdd95.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DY-A1H8-10A (Blood Derived Normal), aliquot TCGA-DY-A1H8-10A-01D-A152-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/898e0cba-2d6b-4049-839f-97146fa5783d

The open-access MAF lists 102 somatic variants for this specimen: 79 protein-altering or splice-affecting, 20 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 66, Silent 20, Nonsense Mutation 8, Frame Shift Ins 2, RNA 2, Intron 1, Frame Shift Del 1, Splice Site 1, In Frame Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.4012C>T p.Q1338* | Nonsense Mutation (SNP) | VAF 66/78 reads (85%) | hotspot (GDC flag); catalogued as rs121913327, CM930029, COSV57325971; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- KRAS | c.34G>T p.G12C | Missense Mutation (SNP) | VAF 128/207 reads (62%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- TTC7A | c.1250G>A p.W417* | Nonsense Mutation (SNP) | VAF 47/98 reads (48%) | catalogued as rs1558568116, COSV55408766; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ACIN1 | c.443T>G p.L148R | Missense Mutation (SNP) | VAF 29/79 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV52973723; called by muse, mutect2, varscan2
- ACTL7B | c.245G>A p.R82H | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT tolerated (0.09); PolyPhen benign (0.001); catalogued as COSV65926906; called by muse, mutect2, varscan2
- ADRA1A | c.1222G>T p.A408S | Missense Mutation (SNP) | VAF 36/72 reads (50%) | SIFT tolerated, low confidence (0.97); PolyPhen benign (0.003); catalogued as COSV52357767, COSV52367780; called by muse, mutect2, varscan2
- ALOX12 | c.1812+1G>A p.X604_splice | Splice Site (SNP) | VAF 16/28 reads (57%) | catalogued as COSV52348775, COSV52351478; called by muse, mutect2, varscan2
- AOC3 | c.881A>T p.N294I | Missense Mutation (SNP) | VAF 25/51 reads (49%) | SIFT tolerated (0.13); PolyPhen benign (0.068); catalogued as COSV53824445; called by muse, mutect2, varscan2
- B3GNT4 | c.737T>C p.V246A | Missense Mutation (SNP) | VAF 34/50 reads (68%) | SIFT deleterious (0.04); PolyPhen benign (0.053); catalogued as COSV57335865; called by muse, mutect2, varscan2
- BPIFC | c.980T>C p.I327T | Missense Mutation (SNP) | VAF 30/83 reads (36%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.875); catalogued as COSV55911099; called by muse, mutect2, varscan2
- CBX2 | c.409C>T p.R137C | Missense Mutation (SNP) | VAF 22/47 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53968547; called by muse, mutect2, varscan2
- CCDC172 | c.337A>G p.T113A | Missense Mutation (SNP) | VAF 58/225 reads (26%) | SIFT tolerated (0.11); PolyPhen benign (0.013); catalogued as COSV100319721; called by muse, mutect2, varscan2
- CFAP54 | c.7829T>G p.L2610R | Missense Mutation (SNP) | VAF 20/62 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100733086, COSV61573580; called by muse, mutect2, varscan2
- CHD7 | c.7504C>G p.L2502V | Missense Mutation (SNP) | VAF 45/114 reads (39%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.458); catalogued as COSV71107543; called by muse, mutect2, varscan2
- CMKLR1 | c.735C>G p.C245W (on ENST00000312143 / NM_001142344.2; = p.C243W on NM_004072.3) | Missense Mutation (SNP) | VAF 25/79 reads (32%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.72); catalogued as COSV56436543; called by muse, mutect2, varscan2
- CMKLR1 | c.734G>T p.C245F (on ENST00000312143 / NM_001142344.2; = p.C243F on NM_004072.3) | Missense Mutation (SNP) | VAF 25/80 reads (31%) | SIFT tolerated (0.78); PolyPhen benign (0.007); catalogued as COSV56436553; called by muse, mutect2, varscan2
- COL4A5 | c.2176G>T p.A726S | Missense Mutation (SNP) | VAF 111/227 reads (49%) | SIFT tolerated (0.42); PolyPhen benign (0.009); catalogued as COSV60356915; called by muse, mutect2, varscan2
- CYTH1 | c.811G>A p.G271R | Missense Mutation (SNP) | VAF 36/82 reads (44%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.807); catalogued as rs778692007, COSV63118691; called by muse, mutect2, varscan2
- DDR2 | c.2560G>A p.D854N | Missense Mutation (SNP) | VAF 34/87 reads (39%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0); catalogued as rs771898787, COSV63369618; called by muse, mutect2, varscan2
- DHX36 | c.1622C>T p.P541L | Missense Mutation (SNP) | VAF 124/264 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as COSV57671126; called by muse, mutect2, varscan2
- FAM47C | c.1841G>A p.R614H | Missense Mutation (SNP) | VAF 55/102 reads (54%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.934); catalogued as rs782535331, COSV63723697; called by muse, mutect2, varscan2
- FAT4 | c.7543T>G p.F2515V | Missense Mutation (SNP) | VAF 47/102 reads (46%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); catalogued as COSV100628198, COSV58683458; called by muse, mutect2, varscan2
- FZR1 | c.484C>T p.R162W | Missense Mutation (SNP) | VAF 15/31 reads (48%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.676); catalogued as rs200022187, COSV58050496; called by muse, mutect2, varscan2
- GRM5 | c.1170T>G p.H390Q | Missense Mutation (SNP) | VAF 17/30 reads (57%) | SIFT tolerated (0.58); PolyPhen benign (0.001); catalogued as COSV59593170; called by muse, mutect2, varscan2
- HHATL | c.557G>A p.R186H | Missense Mutation (SNP) | VAF 36/77 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs761217421, COSV60041036; called by muse, mutect2, varscan2
- HK3 | c.1166C>T p.A389V | Missense Mutation (SNP) | VAF 13/28 reads (46%) | SIFT tolerated (0.25); PolyPhen benign (0.009); catalogued as rs767209073, COSV52837339; called by muse, mutect2, varscan2
- HLTF | c.463G>T p.E155* | Nonsense Mutation (SNP) | VAF 35/92 reads (38%) | catalogued as COSV59499072, COSV59500909; called by muse, mutect2, varscan2
- HMCN1 | c.8335G>C p.D2779H | Missense Mutation (SNP) | VAF 89/351 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs765146245, COSV99627556; called by muse, mutect2, varscan2
- HOXD1 | c.812C>T p.T271M | Missense Mutation (SNP) | VAF 56/155 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58923160; called by muse, mutect2, varscan2
- HSF2 | c.1018C>T p.P340S | Missense Mutation (SNP) | VAF 17/227 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.336); catalogued as COSV100869671; called by muse, mutect2
- IGHG2 | c.433G>A p.V145M | Missense Mutation (SNP) | VAF 37/87 reads (43%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.547); catalogued as rs368453065; called by muse, mutect2, varscan2
- IRS1 | c.2956C>T p.R986W | Missense Mutation (SNP) | VAF 15/33 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.425); catalogued as rs767686104, COSV59334062; called by muse, mutect2, varscan2
- KIF4A | c.103G>A p.V35M | Missense Mutation (SNP) | VAF 31/80 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.835); catalogued as COSV53452330; called by muse, mutect2, varscan2
- KIF7 | c.1955G>A p.G652E | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1411427676, COSV67997417; called by muse, mutect2, varscan2
- KLHL42 | c.439G>T p.E147* | Nonsense Mutation (SNP) | VAF 13/42 reads (31%) | catalogued as COSV67145664; called by muse, mutect2, varscan2
- LRRFIP1 | c.799G>A p.D267N (on ENST00000392000 / NM_001137552.2; = p.D243N on NM_004735.4) | Missense Mutation (SNP) | VAF 23/77 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as rs780318201, COSV55249463; called by muse, mutect2, varscan2
- MAGEA1 | c.781C>T p.R261C | Missense Mutation (SNP) | VAF 48/120 reads (40%) | SIFT tolerated (0.1); PolyPhen benign (0.01); catalogued as rs376229047, COSV63119213; called by muse, mutect2, varscan2
- MAGEE2 | c.314C>T p.T105M | Missense Mutation (SNP) | VAF 24/52 reads (46%) | SIFT deleterious (0.02); PolyPhen benign (0.259); catalogued as rs774700498, COSV64897174; called by muse, mutect2, varscan2
- MEGF6 | c.3692C>T p.T1231M | Missense Mutation (SNP) | VAF 48/57 reads (84%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs753892111, COSV53886788; called by muse, mutect2, varscan2
- MIA3 | c.1613G>T p.G538V | Missense Mutation (SNP) | VAF 52/101 reads (51%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.543); catalogued as COSV60510369; called by muse, mutect2, varscan2
- MUC16 | c.4429T>C p.S1477P | Missense Mutation (SNP) | VAF 38/83 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.934); catalogued as COSV67448407; called by muse, mutect2, varscan2
- NBN | c.1982C>A p.S661* | Nonsense Mutation (SNP) | VAF 105/200 reads (53%) | catalogued as COSV55371498; called by muse, mutect2, varscan2
- NBN | c.740G>A p.G247E | Missense Mutation (SNP) | VAF 45/155 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99619342; called by muse, mutect2, varscan2
- NCKAP5 | c.3417G>T p.E1139D | Missense Mutation (SNP) | VAF 86/200 reads (43%) | SIFT tolerated (0.06); PolyPhen benign (0.038); catalogued as COSV58429797; called by muse, mutect2, varscan2
- OMD | c.835C>A p.L279I | Missense Mutation (SNP) | VAF 107/275 reads (39%) | SIFT tolerated (0.34); PolyPhen benign (0.068); catalogued as rs1311679476, COSV65020038; called by muse, mutect2, varscan2
- OR5W2 | c.872G>A p.S291N | Missense Mutation (SNP) | VAF 42/102 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV60614774, COSV60615520; called by muse, varscan2
- PAH | c.1334G>T p.C445F | Missense Mutation (SNP) | VAF 53/103 reads (51%) | SIFT tolerated (0.05); PolyPhen benign (0.079); catalogued as COSV61014353; called by muse, mutect2, varscan2
- PCDHA9 | c.103G>A p.V35I | Missense Mutation (SNP) | VAF 28/63 reads (44%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.123); catalogued as rs782567110, COSV65323587; called by muse, mutect2, varscan2
- PGR | c.2218C>T p.R740* | Nonsense Mutation (SNP) | VAF 47/139 reads (34%) | catalogued as rs1315135533, COSV54796997; called by muse, mutect2, varscan2
- PLA1A | c.677G>A p.R226Q | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT tolerated (0.05); PolyPhen benign (0.057); catalogued as rs200921577, COSV56330613; called by muse, mutect2, varscan2
- PLD2 | c.1570C>T p.R524W | Missense Mutation (SNP) | VAF 44/100 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.586); catalogued as rs747369203, COSV54003857; called by muse, mutect2, varscan2
- PRKCI | c.607A>G p.M203V | Missense Mutation (SNP) | VAF 74/168 reads (44%) | SIFT tolerated (0.83); PolyPhen benign (0.001); catalogued as rs763902996, COSV99855773; called by muse, varscan2
- PTEN | c.442G>T p.A148S | Missense Mutation (SNP) | VAF 58/143 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.371); catalogued as COSV100910076, COSV64297068; called by muse, mutect2, varscan2
- PXDN | c.2353C>T p.R785* | Nonsense Mutation (SNP) | VAF 25/55 reads (45%) | catalogued as rs1316655042, COSV99413112; called by muse, mutect2, varscan2
- RAI2 | c.1052G>A p.R351Q | Missense Mutation (SNP) | VAF 19/68 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.947); catalogued as rs140631545, COSV58963272; called by muse, mutect2, varscan2
- RIPK3 | c.1132C>T p.Q378* | Nonsense Mutation (SNP) | VAF 13/34 reads (38%) | catalogued as COSV53474399; called by muse, mutect2, varscan2
- ROBO2 | c.124G>A p.V42I | Missense Mutation (SNP) | VAF 17/61 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs778684665, COSV59899211; called by muse, mutect2, varscan2
- SAMD9L | c.2378A>G p.Q793R | Missense Mutation (SNP) | VAF 22/94 reads (23%) | SIFT tolerated (0.23); PolyPhen benign (0.165); catalogued as COSV59079928; called by muse, mutect2, varscan2
- SDHA | c.367T>A p.F123I | Missense Mutation (SNP) | VAF 31/67 reads (46%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.172); catalogued as COSV53765818; called by muse, mutect2, varscan2
- SEC14L5 | c.1972G>T p.D658Y | Missense Mutation (SNP) | VAF 22/56 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV52036766; called by muse, mutect2, varscan2
- SLC12A4 | c.542C>A p.P181Q | Missense Mutation (SNP) | VAF 38/84 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV100311670; called by muse, mutect2, varscan2
- SLC15A2 | c.428C>T p.T143I | Missense Mutation (SNP) | VAF 45/90 reads (50%) | SIFT tolerated (0.64); PolyPhen benign (0.003); catalogued as rs371513641; called by muse, mutect2, varscan2
- SMARCA2 | c.1489C>T p.R497W | Missense Mutation (SNP) | VAF 23/47 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61805119; called by muse, mutect2, varscan2
- SRRM4 | c.110C>T p.T37M | Missense Mutation (SNP) | VAF 31/94 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs1306060661, COSV57409695; called by muse, mutect2, varscan2
- ST3GAL1 | c.1003C>T p.R335W | Missense Mutation (SNP) | VAF 29/54 reads (54%) | PolyPhen probably damaging (0.931); catalogued as rs1399830210, COSV60610744; called by muse, mutect2, varscan2
- TAS2R5 | c.556G>A p.V186I | Missense Mutation (SNP) | VAF 107/238 reads (45%) | SIFT tolerated (0.56); PolyPhen benign (0.057); catalogued as rs543303670, COSV99924781; called by muse, mutect2, varscan2
- TDRD5 | c.1236dup p.Q413Tfs*13 | Frame Shift Ins (INS) | VAF 71/267 reads (27%) | catalogued as rs1433075758; called by mutect2, varscan2
- TENM4 | c.5656A>G p.T1886A | Missense Mutation (SNP) | VAF 51/104 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); catalogued as COSV53611638; called by muse, mutect2, varscan2
- TEX15 | c.6323A>C p.K2108T (on ENST00000256246; = p.K2491T on NM_001350162.2) | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT tolerated (0.12); PolyPhen benign (0.046); catalogued as COSV56342336; called by muse, mutect2, varscan2
- TICRR | c.5357G>A p.G1786E | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as rs1185085166, COSV51538445, COSV51543082; called by muse, mutect2, varscan2
- TLR9 | c.2576G>A p.R859Q | Missense Mutation (SNP) | VAF 32/64 reads (50%) | SIFT tolerated (0.57); PolyPhen benign (0.007); catalogued as rs763585272, COSV62345721; called by muse, mutect2, varscan2
- TTC7A | c.1655T>G p.M552R | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.213); catalogued as COSV99766306; called by muse, mutect2, varscan2
- UROS | c.123G>T p.L41F | Missense Mutation (SNP) | VAF 42/102 reads (41%) | SIFT tolerated (0.07); PolyPhen benign (0.315); catalogued as COSV100908869; called by muse, mutect2, varscan2
- WDR26 | c.2023C>A p.H675N (on ENST00000414423 / NM_001379403.1; = p.H575N on NM_025160.7) | Missense Mutation (SNP) | VAF 26/94 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.627); catalogued as COSV54353474; called by muse, mutect2, varscan2
- WSCD2 | c.1204G>A p.E402K | Missense Mutation (SNP) | VAF 36/53 reads (68%) | SIFT deleterious (0.01); PolyPhen benign (0.031); catalogued as COSV54578672, COSV54582968; called by muse, mutect2, varscan2
- ZNF572 | c.721G>A p.E241K | Missense Mutation (SNP) | VAF 22/84 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60001305; called by muse, mutect2, varscan2
- OR1E2 | c.5_9del p.M2Tfs*67 | Frame Shift Del (DEL) | VAF 31/73 reads (42%) | called by mutect2, pindel, varscan2
- PLCB4 | c.544_564dup p.I182_E188dup | In Frame Ins (INS) | VAF 12/28 reads (43%) | called by mutect2, varscan2
- WASF3 | c.297dup p.A100Sfs*20 | Frame Shift Ins (INS) | VAF 86/180 reads (48%) | called by mutect2, pindel, varscan2
- CNTNAP5 | c.516C>T p.Y172= | Silent (SNP) | VAF 28/69 reads (41%) | catalogued as rs368252422, COSV70484949; called by muse, mutect2, varscan2
- COL4A2 | c.1314G>C p.G438= | Silent (SNP) | VAF 14/28 reads (50%) | catalogued as COSV64625335; called by muse, mutect2, varscan2
- CYLC2 | c.315C>T p.V105= | Silent (SNP) | VAF 36/87 reads (41%) | catalogued as rs1351461041, COSV66336262; called by muse, mutect2, varscan2
- DNAH5 | c.7620G>A p.T2540= | Silent (SNP) | VAF 41/101 reads (41%) | catalogued as rs541631905, COSV54202468; ClinVar: likely benign; called by muse, mutect2, varscan2
- ENPP6 | c.90G>T p.L30= | Silent (SNP) | VAF 19/50 reads (38%) | catalogued as COSV57066239; called by muse, mutect2, varscan2
- EP400 | c.126C>T p.F42= | Silent (SNP) | VAF 15/50 reads (30%) | catalogued as rs139666996, COSV57764426; called by muse, mutect2, varscan2
- GCN1 | c.1806C>T p.H602= | Silent (SNP) | VAF 20/67 reads (30%) | catalogued as rs938227067, COSV56104466; called by muse, mutect2, varscan2
- KCNT1 | c.1116C>T p.N372= (on ENST00000488444; = p.N391= on NM_020822.3) | Silent (SNP) | VAF 44/99 reads (44%) | catalogued as rs374015551, COSV99705177; ClinVar: likely benign; called by muse, mutect2, varscan2
- KDM4B | c.489C>T p.R163= | Silent (SNP) | VAF 16/36 reads (44%) | catalogued as rs754414783, COSV50209705; called by muse, mutect2, varscan2
- LAMA4 | c.2967C>A p.S989= (on ENST00000230538 / NM_001105206.3; = p.S982= on NM_002290.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 28/52 reads (54%) | catalogued as COSV57892586; called by muse, mutect2, varscan2
- MYEF2 | c.510C>A p.P170= | Silent (SNP) | VAF 84/238 reads (35%) | catalogued as COSV51046159; called by muse, mutect2, varscan2
- NLRP7 | c.1479C>T p.H493= | Silent (SNP) | VAF 30/60 reads (50%) | catalogued as rs763029701, COSV60171565; called by muse, mutect2, varscan2
- PADI6 | c.561G>A p.T187= | Silent (SNP) | VAF 35/48 reads (73%) | catalogued as rs761739312, COSV61883817; called by muse, mutect2, varscan2
- PDIA5 | c.1173G>A p.T391= | Silent (SNP) | VAF 13/31 reads (42%) | catalogued as rs749127300, COSV60247387; called by muse, mutect2, varscan2
- PITPNM1 | c.3396C>T p.Y1132= | Silent (SNP) | VAF 66/127 reads (52%) | catalogued as rs753198689, COSV54159868; called by muse, mutect2, varscan2
- POU3F4 | c.336C>T p.N112= | Silent (SNP) | VAF 69/152 reads (45%) | catalogued as rs1333994074, COSV64537768; called by muse, mutect2, varscan2
- RBM26 | c.2865G>A p.L955= (on ENST00000438737 / NM_001366735.2; = p.L928= on NM_022118.5) | Silent (SNP) | VAF 41/125 reads (33%) | catalogued as COSV57391720; called by muse, mutect2, varscan2
- SPATA31A1 | c.1431C>T p.P477= | Silent (SNP) | VAF 21/38 reads (55%) | catalogued as rs1487417707; called by muse, mutect2, varscan2
- STK32A | c.300G>A p.V100= | Silent (SNP) | VAF 16/42 reads (38%) | catalogued as rs980277204, COSV60415452; called by muse, mutect2, varscan2
- ZGRF1 | c.2421C>T p.G807= | Silent (SNP) | VAF 62/120 reads (52%) | catalogued as COSV52199126; called by muse, mutect2, varscan2
- MIR758 | n.50C>T | RNA (SNP) | VAF 28/66 reads (42%) | catalogued as rs762411251; called by muse, mutect2, varscan2
- NADK | c.263+2076A>T | Intron (SNP) | VAF 29/33 reads (88%) | catalogued as COSV58269819; called by muse, mutect2, varscan2
- WASF4P | n.1481A>C | RNA (SNP) | VAF 29/126 reads (23%) | called by muse, mutect2, varscan2
